Somatic mutation profile of tumor specimen TCGA-FI-A2D2-01A (aliquot TCGA-FI-A2D2-01A-11D-A17D-09) from TCGA case TCGA-FI-A2D2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 66.4 years (24,260 days).
Specimen TCGA-FI-A2D2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06b0a751-fad8-4a9a-b560-5d531f5898e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FI-A2D2-10A (Blood Derived Normal), aliquot TCGA-FI-A2D2-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ac5b87c-5967-47bb-b863-033058f54597

The open-access MAF lists 45 somatic variants for this specimen: 36 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 8, Frame Shift Del 2, Splice Site 1, In Frame Del 1, Frame Shift Ins 1, Nonsense Mutation 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 21/26 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.613T>A p.Y205N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1057520008, CD100447, COSV52760580, COSV52806341, COSV52877975, COSV52979708; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AK7 | c.146T>G p.I49S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV50870246; called by muse, mutect2, varscan2
- CDX2 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV66829324; called by muse, mutect2, varscan2
- CENPF | c.8450C>G p.S2817C | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.644); catalogued as COSV65273743; called by muse, mutect2, varscan2
- CHD4 | c.2336G>A p.R779Q (on ENST00000357008 / NM_001363606.2; = p.R792Q on NM_001273.5) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58897494; called by muse, mutect2, varscan2
- CNDP2 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1351554282, COSV60839430; called by muse, mutect2, varscan2
- CNGB1 | c.3331G>A p.A1111T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs199660047, COSV51899213; called by muse, mutect2, varscan2
- DMD | c.8297T>A p.L2766Q | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58901266; called by muse, mutect2, varscan2
- DNAH6 | c.1607G>T p.G536V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs1390099547, COSV52854737, COSV99408691; called by muse, mutect2, varscan2
- DRP2 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as rs1333133641, COSV65809883, COSV65811930; called by muse, mutect2, varscan2
- DSTYK | c.1098C>G p.H366Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV65685987; called by muse, mutect2, varscan2
- ECD | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs150022527; called by muse, mutect2, varscan2
- FAM171A1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.191); catalogued as rs1481950266, COSV65314967; called by muse, mutect2, varscan2
- GBP6 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs374217096; called by muse, mutect2, varscan2
- HMGCLL1 | c.485T>A p.V162D | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV51442701; called by muse, mutect2
- KCNE1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs150454912; ClinVar: uncertain significance; called by mutect2, varscan2
- KHDRBS2 | c.92-1G>T p.X31_splice | Splice Site (SNP) | VAF 47/100 reads (47%) | catalogued as COSV55439873; called by muse, mutect2, varscan2
- LRRIQ3 | c.505C>A p.H169N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs759744331, COSV63042491, COSV63042988; called by muse, varscan2
- NFE2L3 | c.1826_1828del p.D609del | In Frame Del (DEL) | VAF 12/25 reads (48%) | catalogued as rs760146146; called by pindel, varscan2
- OR52I1 | c.908A>G p.Q303R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV56168081; called by muse, mutect2, varscan2
- OTOP2 | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.52); PolyPhen benign (0.061); catalogued as rs202152813, COSV100173078, COSV58881244; called by muse, mutect2, varscan2
- PDE5A | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV53346725; called by muse, mutect2, varscan2
- PLEKHJ1 | c.276C>G p.S92R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55553997, COSV99677855; called by muse, mutect2, varscan2
- RHCE | c.872C>G p.P291R | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as CM096722, COSV53799323, COSV99603783; called by muse, mutect2, varscan2
- SPAG5 | c.2125G>T p.E709* | Nonsense Mutation (SNP) | VAF 15/240 reads (6%) | catalogued as COSV58801017; called by muse, mutect2
- TMX4 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV55680212; called by muse, mutect2, varscan2
- TP53 | c.612G>C p.E204D | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV52750941, COSV52878039; called by muse, mutect2, varscan2
- TTN | c.3467T>C p.I1156T (on ENST00000591111; = p.I1110T on NM_003319.4) | Missense Mutation (SNP) | VAF 46/140 reads (33%) | PolyPhen benign (0.23); catalogued as COSV59964923, COSV60358153; called by muse, mutect2, varscan2
- UBA6 | c.3023C>T p.T1008I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.728); catalogued as rs749859252, COSV59175644; called by muse, varscan2
- ZMYM3 | c.2685G>A p.P895= | Splice Region (SNP) | VAF 19/40 reads (48%) | catalogued as rs142895941, COSV58736957; called by muse, mutect2, varscan2
- ZNF780A | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs199635390, COSV61814941; called by muse, mutect2, varscan2
- HNF1B | c.1164_1174del p.S388Rfs*8 | Frame Shift Del (DEL) | VAF 14/24 reads (58%) | called by mutect2, varscan2
- PRMT3 | c.1247dup p.C417Lfs*4 | Frame Shift Ins (INS) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- TP53 | c.181_182del p.D61* | Frame Shift Del (DEL) | VAF 14/19 reads (74%) | called by mutect2, pindel, varscan2
- GOLGA2 | c.2631C>G p.V877= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as COSV100360097, COSV57850264; called by muse, mutect2, varscan2
- HNF1B | c.1176C>T p.G392= | Silent (SNP) | VAF 16/26 reads (62%) | called by mutect2, varscan2
- KIAA0232 | c.3357A>T p.G1119= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV56924203; called by muse, mutect2, varscan2
- KLHL21 | c.1506T>C p.H502= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs1376128195, COSV66553172; called by muse, mutect2
- OR10G4 | c.660C>T p.I220= | Silent (SNP) | VAF 81/219 reads (37%) | catalogued as rs1338777128, COSV100305045, COSV57977173; called by muse, mutect2, varscan2
- YLPM1 | c.5385G>T p.L1795= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV53108956; called by muse, mutect2
- ZFHX4 | c.9006G>A p.T3002= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1408037634, COSV50651206; called by mutect2, varscan2
- ZNF536 | c.858C>T p.R286= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs770180821, COSV62821537; called by muse, mutect2
- BACE2 | c.312+10615G>C | Intron (SNP) | VAF 64/233 reads (27%) | catalogued as COSV57738521; called by muse, mutect2, varscan2
